Gene-level copy-number profile of tumor specimen TCGA-CQ-A4CI-01A from TCGA case TCGA-CQ-A4CI, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 73.0 years (26,664 days).
Specimen TCGA-CQ-A4CI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.eee0aa61-165a-462e-8bcc-751ed8590c15.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CQ-A4CI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/591e8ce2-63c3-4449-8cbf-7e793d8ca307

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 21,527; copy number 2: 31,721; copy number 3: 5,703; copy number 4: 515; copy number 5: 247; copy number 6: 18; copy number 15: 32; copy number 19: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CQ-A4CI-01A-11D-A25X-01): tumor purity 0.8, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:129,771,596–130,967,575, 8 genes: LINC02465, EEF1GP8, LINC02479, PGBD4P4, GAPDHP56, AC093831.2, AC093831.1, AC093902.1.
- chr9:19,705,338–19,705,655, 1 gene: C11orf98P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 336 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:212,581,357–213,284,205, 12 genes, copy number 6: AC093865.1, LINC01878, PCED1CP, AC108066.1, MIR4776-1, MIR4776-2, AC108066.2, IKZF2, AC079610.1, LINC01953, AC079610.2, SPAG16-DT.
- chr8:35,235,475–43,674,591, 192 genes, copy number 5 (broad region; genes not listed).
- chr9:94,726,604–95,087,159, 1 gene, copy number 5 (within-gene range 4–5): AOPEP.
- chr9:94,900,429–96,655,317, 46 genes, copy number 5: AL807757.2, AL353768.1, AL353768.2, MIR6081, MIR23B, MIR27B, MIR3074, MIR24-1, FANCC, AL354893.2, AL354893.1, RNA5SP288, AL157384.1, AL161729.3, MT1P1, PTCH1, AL161729.2, AL161729.1, AL161729.4, AL392185.1, AL354861.2, AL354861.1, LINC00476, AL354861.3, RNU2-46P, ERCC6L2, RNA5SP289, AL161454.1, LINC00092, AL449403.1, Y_RNA, AL449403.2, AL449403.3, EIF4BP3, HSD17B3, AL160269.1, HSD17B3-AS1, RNU6-1160P, SLC35D2, ZNF367, NSA2P7, AL133477.1, AL133477.2, HABP4, CDC14B, PRXL2C.
- chr10:35,008,551–38,466,176, 71 genes, copy number 15–19 (broad region; genes not listed).
- chr11:103,675,994–104,682,581, 8 genes, copy number 5: AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1, AP003304.1, LINC02552, AP001485.1.
- chr17:22,530,612–22,606,703, 6 genes, copy number 6 (within-gene range 1–6): MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1.

Autosomal genes at a single copy (total copy number 1): 19,106. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
